Somatic mutation profile of tumor specimen TCGA-DD-AAW3-01A (aliquot TCGA-DD-AAW3-01A-11D-A40P-10) from TCGA case TCGA-DD-AAW3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.1 years (25,254 days).
Specimen TCGA-DD-AAW3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0e860b0-87c8-475f-9197-e13585fabd8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAW3-10A (Blood Derived Normal), aliquot TCGA-DD-AAW3-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0682739a-77d9-4113-b10d-95433d55f902

The open-access MAF lists 111 somatic variants for this specimen: 82 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 26, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 3, Splice Region 2, Intron 1, 5'UTR 1, 3'Flank 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 89/107 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.7279C>A p.P2427T (on ENST00000614293; = p.P2397T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV99686976; called by muse, mutect2, varscan2
- ADAMTS10 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1412146494, COSV54359748; called by muse, mutect2, varscan2
- AHNAK | c.8047A>G p.I2683V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.107); catalogued as COSV99945883; called by muse, mutect2, varscan2
- AMPD1 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV62418211; called by muse, mutect2, varscan2
- ASZ1 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766532245, COSV99497797; called by muse, mutect2, varscan2
- ATP10A | c.3375C>A p.F1125L | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV100790958; called by muse, mutect2, varscan2
- BAZ2B | c.4036G>T p.E1346* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100600420; called by muse, mutect2, varscan2
- C1QTNF9B | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101158530; called by muse, mutect2, varscan2
- CCDC180 | c.2459T>C p.V820A | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as COSV100826592; called by muse, mutect2
- CCT3 | c.286A>T p.T96S | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99827139; called by muse, mutect2, varscan2
- CDK15 | c.667A>G p.R223G (on ENST00000652192 / NM_001366386.2; = p.R172G on NM_139158.2) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1030353473, COSV99642765; called by muse, mutect2, varscan2
- CDKN2A | c.168C>A p.S56R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs771138120, COSV100445533, COSV58684312, COSV58721014; ClinVar: uncertain significance; called by muse, mutect2
- CFAP97 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99703337; called by muse, mutect2, varscan2
- CHUK | c.1169G>A p.S390N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100957005; called by muse, mutect2, varscan2
- CIBAR2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV73320660; called by muse, mutect2, varscan2
- CST11 | c.273G>T p.W91C | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100983561; called by muse, mutect2, varscan2
- EPB41L1 | c.1151A>C p.K384T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99149139; called by muse, mutect2
- FAM160A2 | c.2771C>A p.A924D (on ENST00000449352 / NM_001098794.2; = p.A938D on NM_032127.4) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99791774; called by muse, mutect2, varscan2
- FGF21 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.812); catalogued as COSV55811466; called by muse, mutect2, varscan2
- FUT7 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.145); catalogued as COSV99686977; called by muse, mutect2, varscan2
- GCLC | c.1625C>A p.S542Y (on ENST00000643939; = p.S540Y on NM_001498.4) | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV99988339; called by muse, mutect2, varscan2
- GIT2 | c.2200C>G p.Q734E (on ENST00000355312 / NM_057169.5; = p.Q656E on NM_014776.5) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100618963; called by muse, mutect2, varscan2
- GLP2R | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV99301659; called by muse, mutect2, varscan2
- HMGB1 | c.620A>T p.D207V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.151); catalogued as COSV100360888; called by muse, mutect2, varscan2
- IKZF4 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100008904; called by muse, mutect2, varscan2
- ING1 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as rs779870514, COSV100311955; called by muse, mutect2, varscan2
- IQGAP2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV99166759; called by muse, mutect2, varscan2
- ITM2B | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV101052291; called by muse, mutect2, varscan2
- JMJD1C | c.5891A>G p.N1964S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs770406797, COSV100550185; called by muse, mutect2, varscan2
- KANSL3 | c.1498A>G p.R500G | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100830940; called by muse, mutect2
- KCNJ1 | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100131254; called by muse, mutect2, varscan2
- KRT86 | c.968A>T p.N323I | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99524872; called by muse, mutect2, varscan2
- LRP1B | c.6427G>A p.G2143R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101253520, COSV101260818; called by muse, mutect2, varscan2
- LRP2 | c.3428G>T p.C1143F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV99786802; called by muse, mutect2, varscan2
- MAGEC3 | c.20G>C p.W7S | Missense Mutation (SNP) | VAF 71/81 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1290329356, COSV100024963, COSV53576172; called by muse, mutect2, varscan2
- MFSD5 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.29); catalogued as COSV100288941; called by muse, mutect2, varscan2
- MKLN1 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100759709; called by muse, mutect2, varscan2
- MROH7 | c.2792G>C p.G931A | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100273008; called by muse, mutect2, varscan2
- NLGN4Y | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 112/139 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100196429; called by muse, mutect2, varscan2
- NOP10 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100182267; called by muse, mutect2, varscan2
- OR1C1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 128/196 reads (65%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.549); catalogued as COSV101376192; called by muse, mutect2, varscan2
- OR8H2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV57947566; called by muse, mutect2, varscan2
- OTOF | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs142370721; called by muse, mutect2, varscan2
- PCDH18 | c.1612G>T p.V538L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as COSV100787077; called by muse, mutect2, varscan2
- PIH1D2 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.119); catalogued as COSV99735280; called by muse, mutect2, varscan2
- PIK3CD | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100740008; called by muse, mutect2, varscan2
- POP4 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV99694476; called by muse, mutect2, varscan2
- PRCC | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as COSV99618489; called by muse, mutect2, varscan2
- PTBP2 | c.844C>T p.R282* (on ENST00000426398 / NM_001300986.2; = p.R274* on NM_021190.4) | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100930180; called by muse, mutect2, varscan2
- PTEN | c.182A>T p.H61L | Missense Mutation (SNP) | VAF 518/1267 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123316, CM110129, COSV64290165, COSV64300390, COSV64310812; called by muse, mutect2, varscan2
- PTPRN | c.2195A>G p.E732G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV55350542; called by muse, mutect2
- RASGEF1A | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV100988642; called by muse, mutect2, varscan2
- RUNX1T1 | c.1471G>A p.A491T (on ENST00000265814 / NM_001198628.1; = p.A464T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs756883632, COSV56146029; called by muse, mutect2, varscan2
- RUVBL2 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); catalogued as COSV55484267; called by muse, mutect2, varscan2
- RYR2 | c.7126G>T p.E2376* | Nonsense Mutation (SNP) | VAF 51/76 reads (67%) | catalogued as COSV100767373, COSV100768390; called by muse, mutect2, varscan2
- SDC4 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs906595150, COSV65595127; called by muse, mutect2, varscan2
- SIGLEC1 | c.3173T>A p.M1058K | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as COSV99163381; called by muse, mutect2, varscan2
- SIGLEC5 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs781270936, COSV99707184; called by muse, mutect2, varscan2
- SLC9C2 | c.439T>A p.W147R | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876591; called by muse, mutect2, varscan2
- SORCS3 | c.3599T>C p.V1200A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs367891062; called by muse, mutect2, varscan2
- SPG11 | c.6691A>G p.I2231V | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99968127; called by muse, mutect2, varscan2
- STIMATE | c.618C>T p.N206= | Splice Region (SNP) | VAF 37/45 reads (82%) | catalogued as rs887132671, COSV100753634; called by muse, mutect2, varscan2
- SUSD5 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV100534950, COSV58881041; called by muse, mutect2, varscan2
- SYT6 | c.590C>T p.A197V (on ENST00000610222 / NM_001366225.1; = p.A112V on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV101059613; called by muse, mutect2, varscan2
- TBATA | c.610T>C p.S204P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100165130; called by muse, mutect2, varscan2
- TP63 | c.882G>A p.Q294= | Splice Region (SNP) | VAF 61/168 reads (36%) | catalogued as COSV99285792; called by muse, mutect2, varscan2
- TPGS1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.325); catalogued as COSV100830754; called by muse, mutect2, varscan2
- TRAM1L1 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV100162026; called by muse, mutect2, varscan2
- TRH | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs149654673; called by muse, mutect2, varscan2
- TTC7A | c.2096T>A p.L699Q | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV99766099; called by muse, mutect2, varscan2
- UNC5CL | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99770614; called by muse, mutect2, varscan2
- ZNF878 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1375796452, COSV101521181; called by muse, mutect2, varscan2
- C9orf131 | c.1870_1871del p.Q624Vfs*19 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | called by mutect2, pindel*, varscan2
- CENPH | c.357del p.S120Afs*11 | Frame Shift Del (DEL) | VAF 93/257 reads (36%) | called by mutect2, pindel, varscan2
- DENND10 | c.519dup p.H174Tfs*50 | Frame Shift Ins (INS) | VAF 90/255 reads (35%) | called by mutect2, pindel, varscan2
- FAM117B | c.1624dup p.M542Nfs*44 | Frame Shift Ins (INS) | VAF 27/67 reads (40%) | called by mutect2, pindel, varscan2
- FZD2 | c.615_620del p.K206_V207del | In Frame Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- PCLO | c.5112_5119del p.D1706* | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | called by mutect2, pindel, varscan2
- PGR | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); called by muse, mutect2
- RPS6KA3 | c.262dup p.I88Nfs*5 | Frame Shift Ins (INS) | VAF 28/96 reads (29%) | called by mutect2, varscan2
- TTC19 | c.990_994+10del p.X330_splice | Splice Site (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- ACTL7B | c.450C>T p.S150= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV65927683; called by muse, mutect2, varscan2
- CBLB | c.2091A>G p.K697= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV51433388, COSV99912815; called by muse, mutect2, varscan2
- CLSTN3 | c.600T>A p.I200= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV99866606; called by muse, mutect2, varscan2
- COPB1 | c.522T>C p.P174= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as COSV99999299; called by muse, mutect2, varscan2
- DDX1 | c.1122G>T p.G374= | Silent (SNP) | VAF 71/177 reads (40%) | catalogued as COSV99245959, COSV99246067; called by muse, mutect2, varscan2
- DHX29 | c.1140A>G p.K380= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV52419549, COSV99287017; called by muse, mutect2, varscan2
- DMD | c.6306T>A p.S2102= | Silent (SNP) | VAF 170/195 reads (87%) | catalogued as COSV100818419; called by muse, mutect2, varscan2
- FLG | c.3522A>T p.G1174= | Silent (SNP) | VAF 59/106 reads (56%) | catalogued as COSV100910671; called by muse, mutect2, varscan2
- GNB3 | c.483G>T p.S161= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV99300926; called by muse, mutect2, varscan2
- GPSM1 | c.1074C>T p.I358= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV100696559; called by muse, mutect2, varscan2
- HOOK1 | c.327C>T p.T109= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs1351608850, COSV100969118, COSV64618614; called by muse, mutect2, varscan2
- HSF1 | c.336T>A p.L112= | Silent (SNP) | VAF 235/334 reads (70%) | catalogued as COSV101275151; called by muse, mutect2, varscan2
- KANSL3 | c.1500A>G p.R500= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV100830939; called by muse, mutect2
- KCNT2 | c.750T>A p.P250= | Silent (SNP) | VAF 345/572 reads (60%) | catalogued as COSV99651863; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2766C>T p.H922= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs747462024, COSV99167717; called by muse, mutect2, varscan2
- MORC1 | c.237C>T p.D79= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as COSV99225263; called by muse, mutect2, varscan2
- OR14C36 | c.891G>A p.V297= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV100507400; called by muse, mutect2, varscan2
- OR2T8 | c.615C>T p.L205= | Silent (SNP) | VAF 107/209 reads (51%) | catalogued as COSV100178095; called by muse, mutect2, varscan2
- PCK2 | c.825T>C p.D275= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99394123; called by muse, mutect2, varscan2
- PCK2 | c.1497C>T p.A499= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV99394125; called by muse, mutect2, varscan2
- PIWIL1 | c.696T>C p.Y232= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99806056; called by muse, mutect2, varscan2
- RNF17 | c.1104T>C p.D368= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV99692363; called by muse, mutect2, varscan2
- SEMA4B | c.624C>T p.S208= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100203002, COSV104408696; called by muse, mutect2, varscan2
- STRIP2 | c.1533C>T p.Y511= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs746244003, COSV99973515; called by muse, mutect2, varscan2
- TTN | c.78853T>C p.L26285= (on ENST00000591111; = p.L18861= on NM_003319.4) | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100597433; called by muse, mutect2, varscan2
- VWF | c.4185G>T p.R1395= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99778200; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57621690 A>G | 3'Flank (SNP) | VAF 20/45 reads (44%) | catalogued as COSV54089679; called by muse, mutect2
- DST | c.4297-2711G>A | Intron (SNP) | VAF 22/113 reads (19%) | catalogued as COSV99751847; called by muse, mutect2, varscan2
- OR2D3 | c.-1A>C | 5'UTR (SNP) | VAF 40/75 reads (53%) | catalogued as COSV100505002; called by muse, mutect2, varscan2
